Somatic mutation profile of tumor specimen TCGA-J4-AATZ-01A (aliquot TCGA-J4-AATZ-01A-11D-A41K-08) from TCGA case TCGA-J4-AATZ, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.3 years (24,226 days).
Specimen TCGA-J4-AATZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eee3f06a-039b-466f-9492-f4eb9127c88b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-AATZ-10A (Blood Derived Normal), aliquot TCGA-J4-AATZ-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/678d0fb2-7a7f-47c4-9d75-349912f0a0d7

The open-access MAF lists 40 somatic variants for this specimen: 32 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 7, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT2 | c.1096G>C p.E366Q | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as COSV99183839; called by muse, mutect2, varscan2
- ANKRD27 | c.134G>C p.S45T | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100043076; called by muse, mutect2
- CARS1 | c.1394A>G p.N465S | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.314); catalogued as COSV99543358; called by muse, mutect2, varscan2
- CDH12 | c.776T>A p.L259H | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101203188; called by muse, mutect2
- DCC | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV100502248; called by muse, mutect2
- EPB41L4B | c.1637T>C p.L546P | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.454); catalogued as COSV101000937; called by muse, mutect2, varscan2
- FANCB | c.2460G>T p.K820N | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100146656; called by muse, mutect2, varscan2
- FAT3 | c.11819G>A p.R3940Q | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.968); catalogued as COSV53191619; called by muse, mutect2, varscan2
- FMO1 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV61446358; called by muse, mutect2, varscan2
- FSCB | c.524C>A p.T175K | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV100469719; called by muse, mutect2, varscan2
- FSTL4 | c.1751A>G p.H584R | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV99533496; called by muse, mutect2
- GRIA2 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV52403065, COSV99645583; called by muse, mutect2
- HYDIN | c.13876G>A p.V4626M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.561); catalogued as rs781658714, COSV101125191; called by mutect2, varscan2
- KCNT2 | c.2645T>C p.F882S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1473850115, COSV99656003; called by muse, mutect2, varscan2
- KSR2 | c.1535C>G p.P512R | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.592); catalogued as COSV100196369; called by muse, mutect2, varscan2
- MSX2 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1484486574, COSV53326576; called by muse, mutect2, varscan2
- MVK | c.514G>C p.D172H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as COSV99950078; called by muse, mutect2, varscan2
- MYO15A | c.3050C>A p.T1017N | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.036); catalogued as COSV99234039; called by muse, mutect2
- NBPF9 | c.176A>C p.K59T | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as rs782557553; called by muse, varscan2
- RYR2 | c.6365C>A p.S2122Y | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.288); catalogued as COSV63707012; called by muse, mutect2
- SEMA4G | c.160C>G p.Q54E | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as COSV99273061; called by muse, varscan2
- SEMA4G | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV99273066; called by muse, varscan2
- SYNCRIP | c.1493G>T p.R498M | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.205); catalogued as COSV100784304; called by muse, mutect2
- THBS3 | c.1768G>C p.D590H | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1490955535, COSV100857685; called by muse, mutect2, varscan2
- THBS3 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.917); catalogued as rs372530953; called by muse, mutect2, varscan2
- USP7 | c.2879A>C p.E960A | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV100784363; called by muse, mutect2
- ZCCHC12 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV100038633; called by muse, mutect2
- ZFP37 | c.1529C>G p.T510S | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.117); catalogued as COSV100953307; called by muse, mutect2, varscan2
- ZNF23 | c.1869A>T p.K623N | Missense Mutation (SNP) | VAF 6/141 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100612240; called by muse, mutect2
- ZNF619 | c.1484C>G p.S495C | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100123340; called by muse, mutect2, varscan2
- GPATCH8 | c.2630_2631insA p.S878Ffs*7 | Frame Shift Ins (INS) | VAF 18/62 reads (29%) | called by pindel, varscan2
- NEO1 | c.2755G>A p.G919S | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2
- GCKR | c.1737A>T p.L579= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99269352; called by muse, mutect2, varscan2
- KCNQ2 | c.900C>T p.I300= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs764404303, COSV100610439; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- LCMT2 | c.1029C>G p.A343= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99980191; called by muse, mutect2, varscan2
- NR2F6 | c.1065G>A p.L355= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99285808; called by muse, mutect2
- PRORP | c.141T>C p.S47= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as rs1371997230, COSV99156204; called by muse, mutect2
- RAB11FIP5 | c.474A>G p.E158= | Silent (SNP) | VAF 46/313 reads (15%) | catalogued as COSV99242378; called by muse, mutect2, varscan2
- VPS54 | c.27A>C p.P9= | Silent (SNP) | VAF 39/124 reads (31%) | catalogued as COSV99708601; called by muse, mutect2, varscan2
- DCHS2 | n.3738C>A | RNA (SNP) | VAF 17/40 reads (43%) | catalogued as COSV100602404; called by muse, mutect2, varscan2
